Somatic mutation profile of tumor specimen TCGA-AO-A0JJ-01A (aliquot TCGA-AO-A0JJ-01A-11W-A071-09) from TCGA case TCGA-AO-A0JJ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 54.1 years (19,758 days).
Specimen TCGA-AO-A0JJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c637d375-0f5f-404e-862e-e5443535f000.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A0JJ-10A (Blood Derived Normal), aliquot TCGA-AO-A0JJ-10A-01W-A071-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8bf26864-2b3c-4fdc-9646-ce593afd41c5

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Frame Shift Del 2, Intron 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTB | c.1004G>C p.R335P | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100079401, COSV59319230; called by muse, mutect2
- ACTG2 | c.1080G>T p.K360N | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV61828748; called by muse, mutect2, varscan2
- CPT1C | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1294043412, COSV54917786, COSV54919822; called by muse, mutect2, varscan2
- ERBIN | c.3851A>T p.H1284L (on ENST00000284037 / NM_001253697.2; = p.H1243L on NM_018695.4) | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52319912; called by muse, mutect2, varscan2
- LRP4 | c.1123dup p.A375Gfs*24 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | catalogued as rs777522999; called by mutect2, pindel
- SERPINA4 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as rs373176783; called by muse, mutect2, varscan2
- SOBP | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV58000799; called by muse, mutect2
- SYPL2 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs775749958, COSV63994819; called by muse, mutect2, varscan2
- UBR4 | c.13701G>T p.E4567D | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100921643, COSV100922193; called by muse, mutect2
- UNC13C | c.5578C>T p.Q1860* | Nonsense Mutation (SNP) | VAF 23/71 reads (32%) | catalogued as COSV52888559; called by muse, mutect2, varscan2
- CDH1 | c.1092_1098del p.V365Tfs*26 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- MED23 | c.3276_3288del p.W1092Cfs*32 | Frame Shift Del (DEL) | VAF 34/93 reads (37%) | called by mutect2, pindel, varscan2
- C10orf71 | c.1584A>G p.R528= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV60509251; called by muse, mutect2, varscan2
- MERTK | c.2910C>T p.S970= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV54931234; called by muse, mutect2, varscan2
- TAF1 | c.4917T>A p.S1639= (on ENST00000373790 / NM_138923.4; = p.S1660= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV52116698; called by muse, mutect2, varscan2
- ZNF75D | c.45G>A p.Q15= | Silent (SNP) | VAF 9/146 reads (6%) | catalogued as COSV100883690, COSV66132779, COSV66132943; called by muse, mutect2
- BTN2A3P | n.1448-239G>T | Intron (SNP) | VAF 25/94 reads (27%) | called by muse, mutect2, varscan2
